Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2H, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2H-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD O.3
Liposarcoma, dedifferentiated
08858/3
Inte. Retroperitoneum
C48.6
JW 3/10/14

Clinical Diagnosis & History:

Recurrent retroperitoneal liposarcoma.

Specimens Submitted:

- 1: Radical resection of recurrent liposarcoma with tail of pancreas, spleen, left colon, greater curve of stomach
- 2: Proximal jejunum

DIAGNOSIS:

1. Radical resection of recurrent liposarcoma with tail of pancreas, spleen, left colon, greater curve of stomach:

A. Small and large bowel tumor:

- Recurrent dedifferentiated liposarcoma with focal areas of well-differentiated/sclerosing liposarcoma and extensive necrosis (see note).
- Tumor size: 15.1 X 8.3 X 6.5 cm.
- The dedifferentiated component of the tumor involves the small bowel segment transmurally with an intraluminal component measuring 5.5 X 5.1 X 3.9 cm. The well-differentiated sclerosing liposarcoma component is adherent to serosal segment of both the small and large bowel segments.
- Necrosis and cyst formation comprise approximately 30% of the tumor, gross estimate.
- Large bowel with reactive/ischemic changes, atrophic pancreatic parenchyma, unremarkable spleen parenchyma.

B. Stomach wedge tumor:

- Well-differentiated/sclerosing liposarcoma adherent to serosal aspect of stomach segment (see note)
- Tumor size: 8.5 X 5.4 X 3.9 cm.
- Areas of dedifferentiation are not identified.

Note: The tumor associated with small and large bowel is composed predominantly (70%) of dedifferentiated liposarcoma component and exhibits an undifferentiated round and plump spindle cell morphology with scattered areas showing a hemangiopericytoma-like pattern. The dedifferentiated areas show extensive areas of necrosis. The component associated with the gastric wedge is entirely composed of well-differentiated/sclerosing type liposarcoma.

** Continued on next page **

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Page 2 of 4

2. Proximal jejunum; excision:

- Segment of small bowel with unremarkable mucosa, serosal fibrous adhesions and multifocal serositis.
- No tumor is identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) Received fresh in a container labeled as "Radical resection of recurrent liposarcoma with tail of pancreas, spleen, left colon, greater curvature of stomach" are multiple excision specimens. A. The main specimen is composed of a mass with a small bowel segment and a large bowel segment entangled in multiple fibrous adhesions, measures overall 29.5 X 14.9 X 9.1 cm. The main mass is a 15.1 X 8.3 X 6.5 cm tan-yellow, lobulated tumor with an outer pseudocapsule and smooth external surface. Upon opening the tumor reveals tan-grey multicystic cut surfaces with multiple areas of necrosis. The cystic/necrotic areas comprise approximately 30% of the tumor. The presumptive anterior aspect of the mass is inked black and the posterior/deep is inked blue. The small bowel segment measures 45.1 cm. in length and upon opening, up to 7.1 cm. in circumference. Two margins are identified which are arbitrarily designated as A and B. The mucosa is tan-red and bears a 5.5 X 5.1 X 3.9 cm. tan-grey fungating mass with multifocal areas of necrosis that is located 6.8 cm. from margin "A". This mass is contiguous with the above described main tumor. The attached segment of large bowel measures 50 cm. in length and upon opening up to 11.2 cm. in circumference. The mucosa is dusky, red-tan and hemorrhagic. The margins are arbitrarily designated A and B. The tumor is not identified involving the large bowel. A small fragment of presumptive pancreatic tissue is identified in relationship with the small bowel segment and measures 2.1 X 2.0 X 1.9 cm. and is identified not involved by tumor.

B. In addition to the main specimen there is an 8.5 X 5.4 X 3.9 cm. separate fragment of lobulated tumor that is adherent to a small segment of stomach is identified. The specimen shows a smooth outer surface and upon sectioning shows fatty appearing yellow-white cut surfaces and a small fragment of gastric mucosa. Also, two tan-pink wedge segments of stomach measuring 5.1 X 3.6 X 2.5 cm and 4.5 X 3.1 X 2.5 cm. are identified which upon opening show unremarkable mucosa with preserved rugae. A 6.9 X 6.1 X 3.5 cm. 65 gram splenectomy specimen with smooth dark-red external surfaces is also identified. Upon sectioning, homogenous dark-red cut surfaces are seen. Representative sections are submitted. Tissue for TPS and gross photos are taken.

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 4

Summary of sections

MT Main tumor
MTA Main tumor anterior
MTP Main tumor posterior
SBMA Small bowel margin A
TSB Tumor to small bowel
PSB Presumptive pancreatic segment
SBMB Small bowel margin B
LBMA Large bowel margin A
LB Large bowel mid
LBMB Large bowel margin B
TS Tumor and stomach wedge
SW Stomach wedges
SP - Spleen

2) The specimen is received fresh, labeled "Proximal jejunum", and consists of a 7.2 cm in length x 4.0 cm in circumference unoriented and kinked segment of small bowel. The margins are stapled and inked (black and blue, respectively). The serosa is adherent between the two margins. A focal amount of peri-mesenteric fat is present. The mucosa is grossly unremarkable. Representative sections are submitted.

Summary of sections:

M1 - one margin, shaved
M2 - opposite margin, shaved
A adhesion
U - uninvolved

Summary of Sections:

Part 1: Radical resection of recurrent liposarcoma with tail of pancreas, spleen, left colon, greater curve of stomach

Blocks	Block Designation	PCs
2	LB	2
1	LBMA	1
1	LBMB	2
7	MT	8
3	MTA	5
1	MTP	1
1	PSB	1
1	SBMA	2
1	SBMB	2
1	SPL	2
2	SW	3
5	TS	5
5	TSB	5

Part 2: Proximal jejunum

Blocks	Block Designation	PCs
3	A	3

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

3 M1 3
2 M2 2
1 U 2

Page 4 of 4

** End of Report **

Prior sarcoma was well-differentiated.
BCR

Source: NCI Genomic Data Commons file 4348e9f4-4eed-485a-9981-83a54a95e634 (TCGA-DX-AB2H.0DFD5500-72EB-46FA-9741-0AFA5D2E61C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).